Gene-level copy-number profile of tumor specimen ALCH-B2RB-TTP1-B from ALCHEMIST case ALCH-B2RB, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 58.3 years (21,281 days).
Specimen ALCH-B2RB-TTP1-B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 979122ca-16b2-489c-8270-586f37ad666c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2RB-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,718 have no estimate.
https://portal.gdc.cancer.gov/files/97fd7d9e-565a-46ec-a95f-05c418190f32

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 14; copy number 1: 9,318; copy number 2: 47,889; copy number 3: 1,470; copy number 4: 191; copy number 5: 15; copy number 6: 3; copy number 7: 1; copy number 10: 3; copy number 26: 1.

Homozygous deletions (total copy number 0; autosomes only): 14 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:3,205,988–3,208,664, 1 gene (within-gene range 0–2): AL512383.1.
- chr7:45,769,105–45,815,263, 2 genes: GTF2IP13, RNU6-241P.
- chr13:113,748,511–113,751,089, 1 gene: LINC00552.
- chr16:1,286,351–1,288,837, 1 gene: TPSP2.
- chr16:1,308,880–1,327,018, 2 genes (within-gene range 0–3): UBE2I, AL031714.1.
- chr16:1,349,240–1,351,878, 1 gene (within-gene range 0–4): TSR3.
- chr17:61,361,668–61,400,243, 2 genes (within-gene range 0–2): AC005746.2, AC005746.1.
- chr19:567,210–572,228, 1 gene (within-gene range 0–3): AC009005.1.
- chr22:46,244,011–46,294,008, 3 genes: CDPF1, PKDREJ, TTC38.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 23 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–71,585, 8 genes, copy number 5–7: DDX11L1, WASH7P, MIR6859-1, MIR1302-2HG, MIR1302-2, OR4G4P, OR4G11P, OR4F5.
- chr9:136,754,386–136,766,255, 2 genes, copy number 5: LCN8, LCN15.
- chr13:18,467,172–18,667,221, 6 genes, copy number 5: ZNF962P, BNIP3P7, LINC00349, LONRF2P2, LINC00388, FEM1AP4.
- chr13:113,648,804–113,658,198, 1 gene, copy number 5: ATP4B.
- chr14:105,597,691–105,601,728, 1 gene, copy number 6 (within-gene range 1–6): IGHE.
- chr16:1,273,751–1,276,522, 1 gene, copy number 6: AC120498.7.
- chr21:43,414,483–43,479,534, 4 genes, copy number 10–26: SIK1, LINC00319, LINC00313, AP001048.1.

Autosomal genes at a single copy (total copy number 1): 6,462. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
